Somatic mutation profile of tumor specimen HCM-BROD-0444-C43-06A (aliquot HCM-BROD-0444-C43-06A-11D-A78T-36) from HCMI case HCM-BROD-0444-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.4 years (22,064 days).
Specimen HCM-BROD-0444-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a849c29c-26b7-48d9-88bc-aaae86a69680.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0444-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0444-C43-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cd45776-3172-464e-bb9c-4d17cda01fad

The open-access MAF lists 927 somatic variants for this specimen: 537 protein-altering or splice-affecting, 284 silent, 106 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 480, Silent 284, Intron 45, Nonsense Mutation 33, 3'UTR 17, RNA 16, 5'Flank 13, Splice Region 9, 5'UTR 8, 3'Flank 7, Frame Shift Del 5, Splice Site 4.

Variants (750 of 927; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1914_1916dup p.T639dup (on ENST00000288602 / NM_001374244.1; = p.T599dup on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 110/247 reads (45%) | catalogued as rs727502902; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NEXMIF | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 43/152 reads (28%) | catalogued as rs878854425, COSV50022161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.5645G>A p.R1882Q | Missense Mutation (SNP) | VAF 90/332 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs794727444, CM136053, CM145316, COSV51836760, COSV51839118; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3203G>A p.G1068E | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.345); catalogued as rs1342193834, COSV55289748; called by muse, mutect2, varscan2
- ABCC9 | c.2417G>A p.G806E | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771669791; called by muse, mutect2, varscan2
- ABI3BP | c.2087G>A p.G696E | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.421); catalogued as COSV52552812; called by muse, mutect2, varscan2
- ACTN3 | c.637-1G>A p.X213_splice | Splice Site (SNP) | VAF 66/217 reads (30%) | catalogued as COSV72207668; called by muse, mutect2, varscan2
- ADAMTS16 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 81/233 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.425); catalogued as rs1418819406; called by muse, mutect2, varscan2
- ADGRF1 | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs762544665; called by muse, mutect2, varscan2
- ADH1A | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 173/367 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV52924354; called by muse, mutect2, varscan2
- AFF2 | c.3781G>A p.D1261N | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV53996155, COSV54007286; called by muse, mutect2, varscan2
- AGTR2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as rs1163188247, COSV64156615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGXT2 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 128/485 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561216704; called by muse, mutect2, varscan2
- AHNAK | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 79/299 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs114553252; called by muse, mutect2, varscan2
- AHSG | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99890047; called by muse, mutect2, varscan2
- ANGPT1 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | catalogued as COSV99863679; called by muse, mutect2
- ANK3 | c.4708C>T p.P1570S | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1003753635; called by muse, mutect2, varscan2
- ANKFN1 | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100593315; called by muse, mutect2, varscan2
- APOB | c.11915G>A p.G3972E | Missense Mutation (SNP) | VAF 105/330 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV51946074; called by muse, mutect2, varscan2
- ARHGAP21 | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1265976883; called by muse, mutect2, varscan2
- ARHGEF12 | c.4442G>A p.G1481E | Missense Mutation (SNP) | VAF 135/528 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV100755197; called by muse, mutect2, varscan2
- ARMC4 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.159); catalogued as COSV53468692; called by muse, mutect2, varscan2
- ASTN2 | c.1957C>T p.R653C (on ENST00000313400 / NM_001365069.1; = p.R602C on NM_014010.5) | Missense Mutation (SNP) | VAF 71/198 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759200691, COSV57763735, COSV57810099; called by muse, mutect2, varscan2
- ASTN2 | c.1493C>T p.S498F (on ENST00000313400 / NM_001365069.1; = p.S447F on NM_014010.5) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as COSV57782772; called by muse, mutect2, varscan2
- ASTN2 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as rs779407243, COSV100529342; called by muse, mutect2, varscan2
- ATP1B4 | c.823G>A p.D275N (on ENST00000218008 / NM_001142447.3; = p.D271N on NM_012069.5) | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV54314240; called by muse, mutect2, varscan2
- ATP8B2 | c.3035C>T p.A1012V (on ENST00000672630; = p.A979V on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV59247685; called by muse, mutect2, varscan2
- BAP1 | c.66C>T p.F22= | Splice Region (SNP) | VAF 251/472 reads (53%) | catalogued as rs1559593101; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP2 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV66577868; called by muse, mutect2, varscan2
- BMP4 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753312749, COSV55415763; called by muse, mutect2, varscan2
- BRINP2 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762582867, COSV64180145; called by muse, mutect2, varscan2
- BSDC1 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 87/337 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs138922587; called by muse, mutect2, varscan2
- C3orf62 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 95/130 reads (73%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as rs770343603, COSV57985227; called by muse, mutect2, varscan2
- C6 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs746657514; called by muse, mutect2, varscan2
- C7 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV57472567; called by muse, mutect2, varscan2
- CACNA1E | c.6922G>A p.E2308K (on ENST00000367573 / NM_001205293.3; = p.E2265K on NM_000721.4) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs769144197; called by muse, mutect2, varscan2
- CAMSAP3 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV99351901; called by muse, mutect2, varscan2
- CCDC185 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as rs1055826533; called by muse, mutect2, varscan2
- CD163L1 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58014686; called by muse, mutect2, varscan2
- CDH6 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs777622672, COSV54064764; called by muse, mutect2, varscan2
- CEACAM21 | c.823G>A p.E275K (on ENST00000401445 / NM_001098506.4; = p.E274K on NM_033543.6) | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV51813263; called by muse, mutect2, varscan2
- CEP152 | c.2020T>G p.C674G | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57858382; called by muse, mutect2, varscan2
- CEP57 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1422459007; called by muse, mutect2, varscan2
- CGNL1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as COSV55569994; called by muse, mutect2, varscan2
- CHRM3 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs780583857; called by muse, mutect2, varscan2
- CHTF18 | c.668T>C p.L223S | Missense Mutation (SNP) | VAF 154/615 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs774782274; called by muse, mutect2, varscan2
- CLEC19A | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV71854365; called by muse, mutect2, varscan2
- CNR2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.441); catalogued as rs567833720, COSV65692174; called by muse, mutect2, varscan2
- CNTNAP4 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 18/103 reads (17%) | catalogued as COSV56698027, COSV56705357; called by muse, mutect2, varscan2
- COBLL1 | c.1211C>T p.S404F (on ENST00000392717; = p.S366F on NM_014900.5) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766568141; called by muse, mutect2, varscan2
- COL14A1 | c.3886C>T p.P1296S | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV52849671, COSV52857235; called by muse, mutect2, varscan2
- CSPG4 | c.5677C>T p.R1893C | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs897200627; called by muse, mutect2, varscan2
- CUX2 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs866861740, COSV55632203; called by muse, mutect2, varscan2
- CYP19A1 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 90/315 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs142652579; called by muse, mutect2, varscan2
- CYP7B1 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 78/440 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV59587400; called by muse, mutect2, varscan2
- DCC | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59110035; called by muse, mutect2, varscan2
- DCX | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 91/293 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as CD010102; called by muse, mutect2, varscan2
- DDX55 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as rs1229217236; called by muse, mutect2, varscan2
- DEFB116 | c.111G>A p.W37* | Nonsense Mutation (SNP) | VAF 45/164 reads (27%) | catalogued as COSV68721937, COSV68722127; called by muse, mutect2, varscan2
- DNAAF5 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 160/286 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs373188379, COSV52417205; called by muse, mutect2
- DNAH10 | c.12895G>A p.E4299K (on ENST00000409039; = p.E4238K on NM_207437.3) | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53022652; called by muse, mutect2, varscan2
- DNAH17 | c.1809G>A p.M603I | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.039); catalogued as COSV101102152; called by muse, mutect2, varscan2
- DNAH5 | c.12631G>A p.E4211K | Missense Mutation (SNP) | VAF 96/460 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762673561, COSV54204698, COSV54216995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.2356C>T p.Q786* | Nonsense Mutation (SNP) | VAF 41/129 reads (32%) | catalogued as COSV54239235, COSV54246940; called by muse, mutect2, varscan2
- DNAH6 | c.6742C>T p.Q2248* | Nonsense Mutation (SNP) | VAF 68/179 reads (38%) | catalogued as rs867541838, COSV99404233; called by muse, mutect2, varscan2
- DNAH7 | c.1451G>A p.S484N | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.07); catalogued as rs1260735627; called by muse, mutect2, varscan2
- DNER | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59162499; called by muse, mutect2, varscan2
- DPPA3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs1476085353, COSV61502941; called by muse, mutect2, varscan2
- DSCAM | c.5455G>A p.E1819K | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV68030907; called by muse, mutect2, varscan2
- EDEM2 | c.705C>T p.V235= | Splice Region (SNP) | VAF 34/102 reads (33%) | catalogued as rs146048652; called by muse, mutect2, varscan2
- ENOX1 | c.1745C>G p.P582R | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54899567; called by muse, mutect2, varscan2
- ENPEP | c.2362C>T p.R788W | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765435416; called by muse, mutect2, varscan2
- EPHB2 | c.1843G>A p.E615K (on ENST00000400191 / NM_001309193.2; = p.E616K on NM_004442.7) | Missense Mutation (SNP) | VAF 101/295 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV65863907; called by muse, mutect2, varscan2
- EXOC4 | c.2056C>T p.L686F | Missense Mutation (SNP) | VAF 102/180 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54115912; called by muse, mutect2, varscan2
- FAM160A2 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs201084258; called by muse, mutect2, varscan2
- FAM71D | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV61295136; called by muse, mutect2, varscan2
- FAT4 | c.12629C>T p.S4210L | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58702376; called by muse, mutect2, varscan2
- FGFR2 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 91/278 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs763622845, COSV60647057, COSV60653143; called by muse, mutect2, varscan2
- FILIP1L | c.2374G>A p.D792N (on ENST00000354552 / NM_182909.3; = p.D552N on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs766486139; called by muse, mutect2, varscan2
- FLG2 | c.4418G>A p.G1473E | Missense Mutation (SNP) | VAF 95/682 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.284); catalogued as COSV66166282; called by muse, mutect2, varscan2
- FLI1 | c.385+8G>A | Splice Region (SNP) | VAF 75/238 reads (32%) | catalogued as rs202161078; called by muse, mutect2, varscan2
- FN3K | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 72/443 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs768119555, COSV100333382; called by muse, mutect2, varscan2
- FOLR1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 104/386 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV100398573, COSV56617235; called by muse, mutect2, varscan2
- FRMPD4 | c.42-4C>T | Splice Region (SNP) | VAF 88/192 reads (46%) | catalogued as rs866518317; called by mutect2, varscan2
- GABRA3 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.086); catalogued as rs868315790, COSV100942422; called by muse, mutect2, varscan2
- GABRA6 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV50881948; called by muse, mutect2, varscan2
- GAPT | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs374776433; called by muse, mutect2, varscan2
- GAS6 | c.1858C>T p.L620F | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.275); catalogued as rs770035055, COSV100581339; called by muse, mutect2, varscan2
- GJA10 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV101005331; called by muse, mutect2, varscan2
- GORAB | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs760812590, COSV63025986; called by muse, mutect2, varscan2
- GPR39 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.034); catalogued as rs778803979; called by muse, mutect2, varscan2
- GRIK4 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70805438; called by muse, mutect2, varscan2
- GRIN2A | c.3965G>A p.G1322E | Missense Mutation (SNP) | VAF 84/290 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV58021494; called by muse, mutect2, varscan2
- GRK1 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 154/398 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766547270; called by muse, mutect2, varscan2
- GZMB | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.069); catalogued as rs763072582, COSV53540596; called by muse, mutect2, varscan2
- HERC5 | c.1966A>G p.K656E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as rs747098849; called by muse, mutect2, varscan2
- HHIP | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 107/237 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs369873424; called by muse, mutect2, varscan2
- HLA-DRB5 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100894586; called by muse, mutect2
- HSD11B1 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 57/304 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373816985, COSV99808336; called by muse, mutect2, varscan2
- HTR2C | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV52220085; called by muse, varscan2
- IGHA2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 96/590 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1555452761; called by muse, varscan2
- IL27RA | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.092); catalogued as COSV54600233; called by muse, mutect2, varscan2
- IL37 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs867056062, COSV54492147; called by muse, mutect2, varscan2
- INHBC | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs149645850; called by muse, mutect2, varscan2
- INPPL1 | c.3322A>G p.T1108A | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV53355646; called by muse, mutect2, varscan2
- JAKMIP2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV54596724; called by muse, mutect2, varscan2
- KCNB2 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 59/375 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV73049213; called by muse, varscan2
- KDM1B | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 30/185 reads (16%) | catalogued as rs1430835643; called by muse, mutect2, varscan2
- KHDRBS2 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55430938; called by muse, mutect2, varscan2
- KIF4B | c.3202G>A p.D1068N | Missense Mutation (SNP) | VAF 98/313 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV70528946, COSV70531999; called by muse, mutect2, varscan2
- KLHL38 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 70/471 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs752428942, COSV58089275; called by muse, mutect2, varscan2
- KMT2D | c.15142del p.R5048Vfs*3 | Frame Shift Del (DEL) | VAF 30/150 reads (20%) | catalogued as CM114909, COSV56421732, COSV56429960, COSV99986057; called by mutect2, pindel, varscan2
- KNDC1 | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV58839212; called by muse, mutect2, varscan2
- LCT | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); catalogued as COSV51555802; called by muse, mutect2, varscan2
- LGALS16 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as rs764476165; called by muse, mutect2, varscan2
- LIN7A | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866830191, COSV54020298; called by muse, mutect2, varscan2
- LIPE | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 83/280 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs752615475; called by muse, mutect2, varscan2
- LMBRD2 | c.1718A>G p.N573S | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1358449572; called by muse, mutect2
- LMO7 | c.2197C>T p.R733C (on ENST00000357063; = p.R414C on NM_005358.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749357751, COSV58532445; called by muse, mutect2, varscan2
- LPCAT2 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | catalogued as rs768233963; called by muse, mutect2, varscan2
- LRFN2 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs1326906123; called by muse, mutect2, varscan2
- LUZP4 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV64218730; called by muse, mutect2, varscan2
- LYN | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs1327427054, COSV70205649; called by muse, mutect2, varscan2
- MAGEB18 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.936); catalogued as COSV57463376, COSV57465510; called by muse, mutect2, varscan2
- MAGEC2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.811); catalogued as rs1362108453; called by muse, mutect2, varscan2
- MAGEC3 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.068); catalogued as rs867666403, COSV100025696, COSV68924062; called by muse, mutect2, varscan2
- MAP2K2 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 121/527 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.426); catalogued as COSV53565396; called by muse, mutect2, varscan2
- MAVS | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63927084; called by muse, mutect2, varscan2
- MBD3L3 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 58/788 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.06); catalogued as rs578047926; called by muse, mutect2
- MGAM | c.4814C>T p.S1605F | Missense Mutation (SNP) | VAF 243/474 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101527335, COSV72073448; called by muse, mutect2, varscan2
- MLXIPL | c.2372T>G p.V791G | Missense Mutation (SNP) | VAF 106/644 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100515152; called by muse, mutect2, varscan2
- MNDA | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1480747048; called by muse, mutect2, varscan2
- MORC1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1453242500, COSV51716702; called by muse, mutect2, varscan2
- MROH2B | c.4307C>T p.S1436L | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs867528082, COSV68182690; called by muse, mutect2, varscan2
- MTMR1 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs782029024; called by muse, mutect2, varscan2
- MUC12 | c.970C>T p.P324S (on ENST00000379442; = p.P181S on NM_001164462.1) | Missense Mutation (SNP) | VAF 412/750 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1377708481; called by muse, mutect2, varscan2
- MUC12 | c.1463C>T p.P488L (on ENST00000379442; = p.P345L on NM_001164462.1) | Missense Mutation (SNP) | VAF 310/577 reads (54%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.556); catalogued as rs1431281550; called by muse, varscan2
- MUC17 | c.6554C>T p.P2185L | Missense Mutation (SNP) | VAF 134/251 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs770277203; called by muse, mutect2, varscan2
- MYH1 | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV56845725; called by muse, mutect2, varscan2
- MYH1 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 83/304 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV56846051, COSV56857179; called by muse, mutect2, varscan2
- MYH1 | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV56847119; called by muse, mutect2
- MYH2 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 161/545 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV55441089; called by muse, mutect2, varscan2
- MYO15A | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 99/322 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs771141820, COSV99234310; called by muse, mutect2, varscan2
- MYO3A | c.3903G>A p.M1301I | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99780590; called by muse, mutect2
- MYOCD | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV58506546; called by muse, mutect2, varscan2
- MYOM1 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99866100; called by muse, mutect2, varscan2
- NAA16 | c.1603C>T p.L535F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101038451; called by muse, mutect2, varscan2
- NALCN | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745318137, COSV99217547; called by muse, mutect2, varscan2
- NDST4 | c.2371C>T p.R791C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as rs1190760162, COSV52107697; called by muse, mutect2, varscan2
- NDST4 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV52115889; called by muse, mutect2, varscan2
- NFKBIE | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 78/434 reads (18%) | PolyPhen benign (0.421); catalogued as COSV51488912; called by muse, varscan2
- NLRP4 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100015586, COSV56709094; called by muse, mutect2, varscan2
- NOL6 | c.2971C>T p.P991S | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.223); catalogued as rs190107267; called by muse, mutect2, varscan2
- NPAP1 | c.1419G>T p.L473F | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV61509891; called by muse, mutect2, varscan2
- NPHS2 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.685); catalogued as rs896307266, CM021649, COSV62635074; called by muse, mutect2, varscan2
- NRG1 | c.1340C>T p.S447L (on ENST00000405005 / NM_013964.5; = p.S452L on NM_013956.5) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.997); catalogued as rs774023178, COSV55151534; called by muse, mutect2, varscan2
- NRXN2 | c.3958G>A p.V1320M | Missense Mutation (SNP) | VAF 133/537 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs780052134; called by muse, mutect2, varscan2
- NSG2 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV100292681, COSV57459529; called by muse, mutect2, varscan2
- NUGGC | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 118/366 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58432839; called by muse, mutect2, varscan2
- NXF3 | c.1493G>A p.S498N | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV67702838; called by muse, mutect2, varscan2
- NXF3 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 66/233 reads (28%) | catalogued as rs755460265, COSV67703268; called by muse, mutect2, varscan2
- OCIAD1 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767850383, COSV51900510; called by muse, mutect2
- OR2G3 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.317); catalogued as COSV60681352; called by muse, mutect2
- OR4C46 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); catalogued as COSV60218496; called by muse, mutect2, varscan2
- OR4E2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201192739, COSV57731367; called by muse, mutect2, varscan2
- OR4K14 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs1420560514; called by muse, mutect2, varscan2
- OR4L1 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370818199, COSV59849562; called by muse, mutect2, varscan2
- OR4N2 | c.507T>A p.C169* | Nonsense Mutation (SNP) | VAF 111/838 reads (13%) | catalogued as COSV60055179; called by muse, mutect2, varscan2
- OR52R1 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs866371519, COSV61888830; called by muse, mutect2, varscan2
- OR5AP2 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs778885273; called by muse, mutect2, varscan2
- OR5B3 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.042); catalogued as COSV100511855; called by muse, mutect2, varscan2
- OR5W2 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 42/137 reads (31%) | catalogued as COSV100747611; called by muse, mutect2, varscan2
- OR6N2 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59412883; called by muse, mutect2, varscan2
- OR6P1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 94/340 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58110179; called by muse, mutect2, varscan2
- OR8D4 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100361960, COSV58431603; called by muse, varscan2
- OR8D4 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV100361964; called by muse, varscan2
- OR8D4 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1262570745, COSV58431502; called by muse, varscan2
- OTUD6A | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 92/364 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57973372; called by muse, mutect2, varscan2
- PCARE | c.3440C>T p.S1147L | Missense Mutation (SNP) | VAF 119/385 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as rs368208413; called by muse, mutect2, varscan2
- PCDHB10 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 115/346 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as rs782669371; called by muse, mutect2, varscan2
- PCDHB10 | c.2321C>T p.S774L | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs267600435, COSV53376257; called by muse, mutect2, varscan2
- PCDHB13 | c.667A>G p.R223G | Missense Mutation (SNP) | VAF 113/766 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as rs1268048388; called by muse, varscan2
- PCDHGA4 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54056472; called by muse, mutect2
- PCDHGA8 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1285768639; called by muse, mutect2, varscan2
- PCDHGC5 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV52760355; called by muse, mutect2, varscan2
- PIBF1 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58325615; called by muse, mutect2, varscan2
- PIWIL2 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs374676378, COSV63249666; called by muse, mutect2, varscan2
- PKHD1L1 | c.1659G>A p.M553I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV65739516; called by muse, varscan2
- PKP2 | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1312027182, COSV50748359; called by muse, varscan2
- PLXNA1 | c.5680C>A p.L1894M | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); catalogued as COSV99302590; called by muse, mutect2, varscan2
- PNCK | c.649G>A p.D217N (on ENST00000340888 / NM_001366975.1; = p.D300N on NM_001039582.3) | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1461755892; called by muse, mutect2, varscan2
- PNPLA1 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 230/469 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100463236; called by muse, mutect2, varscan2
- PRR27 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 100/211 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); catalogued as rs1186870550; called by muse, mutect2, varscan2
- PRSS58 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs147205406; called by muse, mutect2, varscan2
- PSD | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 68/258 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs150370345; called by muse, mutect2, varscan2
- PTPRK | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs867114186; called by muse, mutect2, varscan2
- PTPRR | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355830722, COSV51728664; called by muse, mutect2, varscan2
- PTPRT | c.4191G>A p.M1397I | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61967372; called by muse, mutect2, varscan2
- PXDNL | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62480271; called by muse, mutect2, varscan2
- RAB30 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52626236, COSV52626779; called by muse, mutect2, varscan2
- RAD51AP2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV67587214; called by muse, mutect2, varscan2
- RASAL2 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.145); catalogued as COSV62714389; called by muse, mutect2, varscan2
- RBMXL3 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 87/309 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.636); catalogued as rs1392976094; called by muse, mutect2, varscan2
- RGS3 | c.1184C>T p.S395L (on ENST00000350696 / NM_001282923.2; = p.S283L on NM_017790.4) | Missense Mutation (SNP) | VAF 93/320 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373897901; called by muse, mutect2, varscan2
- RGS7 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.597); catalogued as COSV58539993; called by muse, mutect2
- RIMBP3 | c.2948G>A p.R983K | Missense Mutation (SNP) | VAF 119/792 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as rs755966145; called by muse, mutect2, varscan2
- RLBP1 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 101/346 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51529309; called by muse, mutect2, varscan2
- RNF17 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99692110; called by muse, mutect2, varscan2
- RP1 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 58/368 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs765035454, COSV55119696; called by muse, mutect2, varscan2
- RP1 | c.5609C>T p.S1870F | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1422272166; called by muse, mutect2, varscan2
- RP1 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs1260107484; called by muse, mutect2, varscan2
- RPTOR | c.3821A>G p.N1274S | Missense Mutation (SNP) | VAF 119/237 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs759654534; called by muse, mutect2, varscan2
- RREB1 | c.3560C>T p.T1187I | Missense Mutation (SNP) | VAF 90/163 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs756679413; called by muse, mutect2, varscan2
- RTL3 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 72/330 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as COSV100330084, COSV58184510; called by muse, mutect2, varscan2
- RTN1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV50726341; called by muse, mutect2, varscan2
- SALL1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 143/547 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV51756222; called by muse, mutect2, varscan2
- SALL3 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs745575293, COSV73306215; called by muse, mutect2, varscan2
- SAMD3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV60774705; called by muse, mutect2, varscan2
- SCG2 | c.1449G>T p.W483C | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs750571397, COSV59541860; called by muse, mutect2, varscan2
- SCN11A | c.585G>A p.W195* | Nonsense Mutation (SNP) | VAF 46/96 reads (48%) | catalogued as rs1553641553, COSV56571193; called by muse, mutect2, varscan2
- SCN2A | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV51836882; called by muse, mutect2, varscan2
- SCN3A | c.5852G>A p.G1951E | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs1308612688; called by muse, mutect2, varscan2
- SCN9A | c.4596G>A p.M1532I (on ENST00000303354; = p.M1521I on NM_002977.3) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as COSV57610671; called by muse, mutect2, varscan2
- SEMG2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as rs929540146, COSV65647288; called by muse, mutect2, varscan2
- SEMG2 | c.1510G>A p.G504S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as rs772776203; called by muse, mutect2, varscan2
- SI | c.3212C>T p.P1071L | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52275718; called by muse, mutect2, varscan2
- SLAMF6 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 54/387 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.944); catalogued as COSV63588416; called by muse, mutect2, varscan2
- SLC12A3 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 110/393 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM117094; called by muse, mutect2, varscan2
- SLC22A24 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs765203877, COSV58223350; called by muse, mutect2, varscan2
- SLITRK2 | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV59428313; called by muse, mutect2, varscan2
- SLITRK4 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs868983945, COSV62022882; called by muse, mutect2, varscan2
- SORL1 | c.2804G>A p.W935* | Nonsense Mutation (SNP) | VAF 129/454 reads (28%) | catalogued as COSV52764454, COSV99492493; called by muse, mutect2, varscan2
- SPACA1 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV99389369; called by muse, mutect2, varscan2
- SPATC1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 56/317 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs373999390; called by muse, mutect2, varscan2
- SPDYE4 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 137/373 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as rs374921150; called by muse, mutect2, varscan2
- SPHKAP | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as COSV60875987; called by muse, mutect2, varscan2
- SPRR2G | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 53/356 reads (15%) | PolyPhen benign (0.039); catalogued as rs770290444, COSV64203159; called by muse, mutect2, varscan2
- SRRM5 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs149011418; called by muse, mutect2, varscan2
- ST18 | c.2137C>T p.H713Y | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.955); catalogued as COSV52497758; called by muse, mutect2
- STAP1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as rs189780620, COSV99609211; called by muse, mutect2, varscan2
- STEAP4 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368689133, COSV57328052; called by muse, mutect2, varscan2
- STOX1 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs547404717, COSV53814237; called by muse, mutect2, varscan2
- SVEP1 | c.10177C>T p.H3393Y | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99928565; called by muse, mutect2, varscan2
- SVEP1 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358712140; called by muse, mutect2, varscan2
- SYNE1 | c.11779T>C p.Y3927H | Missense Mutation (SNP) | VAF 112/444 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390497757; called by muse, mutect2, varscan2
- SYNPO2 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV61109264; called by muse, mutect2, varscan2
- TBC1D8B | c.530G>A p.W177* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as rs1556347033; called by muse, mutect2, varscan2
- TEX15 | c.2825G>A p.G942E (on ENST00000256246; = p.G1325E on NM_001350162.2) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as rs1323962609; called by muse, mutect2, varscan2
- TG | c.5021C>T p.P1674L | Missense Mutation (SNP) | VAF 166/1052 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55065477; called by muse, mutect2, varscan2
- THSD7B | c.2378C>T p.S793F | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs1347902701, COSV55656405; called by muse, mutect2, varscan2
- TMEM200A | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 38/131 reads (29%) | catalogued as rs267600806; called by muse, mutect2, varscan2
- TMEM25 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs782802854; called by muse, mutect2, varscan2
- TNR | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 49/397 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV54884015; called by muse, mutect2, varscan2
- TNXB | c.6475G>A p.E2159K (on ENST00000647633; = p.E1912K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/644 reads (15%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.959); catalogued as rs764589468, COSV64472587; called by muse, mutect2, varscan2
- TOP3A | c.1706T>G p.V569G | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1312031662; called by muse, mutect2, varscan2
- TRAPPC9 | c.3076C>T p.P1026S | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.412); catalogued as rs1328343676; called by muse, mutect2
- TRERF1 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 83/413 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.369); catalogued as rs747235795; called by muse, mutect2, varscan2
- TRIM32 | c.263C>A p.T88K | Missense Mutation (SNP) | VAF 172/576 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1006879922; called by muse, mutect2, varscan2
- TRMT2B | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV58620783; called by muse, mutect2, varscan2
- TRRAP | c.442A>T p.T148S | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs782664293; called by muse, mutect2, varscan2
- TSPAN2 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.056); catalogued as COSV65690696; called by muse, mutect2, varscan2
- TTK | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773610148, COSV57881289, COSV57883755; called by muse, mutect2, varscan2
- TTN | c.28807G>A p.E9603K (on ENST00000591111; = p.E8676K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | PolyPhen possibly damaging (0.814); catalogued as COSV60078694; called by muse, mutect2
- UMPS | c.1103T>C p.I368T | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1195203636; called by muse, mutect2, varscan2
- UNC5CL | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 71/388 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV99770893; called by muse, mutect2, varscan2
- URB1 | c.4144C>T p.L1382F | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1184432349; called by muse, mutect2, varscan2
- USH2A | c.10667G>A p.G3556E | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs397517968, COSV100232381, COSV56353201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.2632C>T p.R878C | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs867113130, COSV56352001; called by muse, mutect2, varscan2
- USP50 | c.794C>T p.S265F (on ENST00000616326; = p.S256F on NM_203494.5) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.209); catalogued as COSV73214060; called by muse, mutect2, varscan2
- VAV2 | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.112); catalogued as rs1458657832; called by muse, mutect2, varscan2
- VSTM2A | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 136/278 reads (49%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.986); catalogued as rs548506452, COSV56494837, COSV99043274; called by muse, mutect2, varscan2
- VWA3A | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs867523871; called by muse, mutect2, varscan2
- VWA3A | c.2769G>A p.M923I | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1172418468; called by muse, mutect2, varscan2
- WWC1 | c.2723G>A p.R908Q | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs146212755; called by muse, mutect2, varscan2
- ZIM3 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as COSV54144746; called by muse, mutect2, varscan2
- ZNF560 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); catalogued as rs145492156, COSV100039152; called by muse, mutect2, varscan2
- ZNF572 | c.1379G>A p.R460K | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV60002051, COSV60002574; called by muse, mutect2, varscan2
- ZNF652 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV62947678, COSV62948225; called by muse, mutect2, varscan2
- ZNF716 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); catalogued as rs782641565, COSV70779637; called by muse, mutect2, varscan2
- ZP2 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs1395231500, COSV54813907; called by muse, mutect2, varscan2
- ZSCAN20 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100792716; called by muse, mutect2, varscan2
- ZSCAN20 | c.2462C>T p.P821L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs865914825; called by muse, mutect2, varscan2
- ABCA2 | c.2075G>A p.W692* (on ENST00000614293; = p.W662* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/148 reads (21%) | called by muse, mutect2, varscan2
- ABHD10 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC008397.2 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ACAN | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACHE | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 379/684 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTC1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 105/355 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ACTN3 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS17 | c.2612del p.S871Tfs*16 | Frame Shift Del (DEL) | VAF 117/419 reads (28%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- ADGRG6 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AKR1C4 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- ANKRD13D | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 101/382 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ANKRD31 | c.106T>C p.L36= | Splice Region (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- ANO2 | c.502G>A p.E168K (on ENST00000356134 / NM_001278597.3; = p.E172K on NM_001278596.3) | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ANOS1 | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 84/282 reads (30%) | called by muse, mutect2, varscan2
- ANOS1 | c.44G>A p.W15* | Nonsense Mutation (SNP) | VAF 85/277 reads (31%) | called by muse, mutect2, varscan2
- APAF1 | c.1774del p.M592Cfs*7 (on ENST00000551964 / NM_181861.2; = p.M581Cfs*7 on NM_001160.3) | Frame Shift Del (DEL) | VAF 60/177 reads (34%) | called by mutect2, pindel, varscan2
- ARHGAP40 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 57/261 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF35 | c.457T>C p.W153R | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0); called by mutect2, varscan2
- ASTN1 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BMP6 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BRAT1 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 124/225 reads (55%) | called by muse, mutect2, varscan2
- C17orf67 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1E | c.4461G>A p.M1487I | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CACNA1I | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 170/338 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CALCOCO2 | c.1126T>C p.Y376H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- CALHM1 | c.971G>A p.G324D | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CAMK1D | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMKV | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 107/171 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CARM1 | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CATIP | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC120 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 65/369 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CCDC137 | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 120/297 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- CD163 | c.3019G>A p.D1007N | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CDK19 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 22/124 reads (18%) | called by muse, mutect2, varscan2
- CEP128 | c.3164G>A p.R1055K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CEP192 | c.6619C>T p.P2207S | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP295 | c.4615A>G p.K1539E | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CEPT1 | c.394T>A p.L132M | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP46 | c.6178G>A p.D2060N | Missense Mutation (SNP) | VAF 87/310 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- CFAP54 | c.8669C>T p.S2890L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHAMP1 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CHRNA5 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.38); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLIC5 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 58/317 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMYA5 | c.5530G>A p.E1844K | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL12A1 | c.2243G>A p.G748E | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL1A2 | c.2927G>A p.G976E | Missense Mutation (SNP) | VAF 600/1051 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A1 | c.3476G>A p.G1159E | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A5 | c.4364G>A p.G1455E | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX15 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CPN2 | c.64_76delinsCCTGTCC p.C22_C26delinsPVR | In Frame Del (DEL) | VAF 10/67 reads (15%) | called by pindel, varscan2*
- CPNE3 | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 88/375 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CROCC | c.547T>C p.Y183H | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CSH2 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 178/1249 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CSMD1 | c.8827C>T p.L2943F (on ENST00000520002; = p.L2942F on NM_033225.6) | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CUL4B | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.527); called by muse, varscan2
- CYP2A13 | c.222del p.R76Gfs*60 | Frame Shift Del (DEL) | VAF 30/236 reads (13%) | called by pindel, varscan2
- CYRIA | c.392T>C p.F131S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DCAF8L1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- DCC | c.1140+7A>G | Splice Region (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- DDX55 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DEFB124 | c.198dup p.K67Qfs*3 | Frame Shift Ins (INS) | VAF 31/124 reads (25%) | called by mutect2, pindel, varscan2
- DISC1 | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 159/665 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DLG3 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 144/617 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DMRTC2 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DNAH8 | c.10168G>A p.G3390R | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAJC13 | c.6525+1G>C p.X2175_splice | Splice Site (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- ELOA3C | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 120/1628 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELOVL5 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMID1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMID1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPG5 | c.4378C>T p.Q1460* | Nonsense Mutation (SNP) | VAF 62/189 reads (33%) | called by muse, mutect2, varscan2
- EPYC | c.-13G>A | Splice Region (SNP) | VAF 44/130 reads (34%) | called by muse, mutect2, varscan2
- EYA4 | c.1246G>A p.E416K (on ENST00000531901 / NM_001301013.1; = p.E410K on NM_004100.5) | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM135A | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM170B | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- FAM71E1 | c.605A>C p.K202T (on ENST00000600100 / NM_001308429.2; = p.K186T on NM_138411.3) | Missense Mutation (SNP) | VAF 149/526 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FAM83B | c.2744C>T p.S915F | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, varscan2
- FAM83B | c.2936T>C p.L979P | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.768); called by muse, varscan2
- FASN | c.6575C>T p.S2192L | Missense Mutation (SNP) | VAF 179/799 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FBXO39 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 126/465 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- FHDC1 | c.3422T>A p.L1141* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- FMO3 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- FNBP1 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FREM3 | c.3440G>A p.R1147K | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- FREM3 | c.1284G>A p.M428I | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FRG2B | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 36/704 reads (5%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.79); called by muse, mutect2
- GDF2 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 71/245 reads (29%) | called by muse, mutect2, varscan2
- GLS2 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA6L6 | c.2138G>C p.R713T | Missense Mutation (SNP) | VAF 68/591 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); called by muse, mutect2
- GRINA | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 81/321 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GSDMC | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HDAC4 | c.760_763del p.S254Gfs*2 | Frame Shift Del (DEL) | VAF 93/233 reads (40%) | called by mutect2, pindel, varscan2
- HOXB5 | c.747G>A p.W249* | Nonsense Mutation (SNP) | VAF 125/390 reads (32%) | called by muse, mutect2, varscan2
- HSD11B1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- HSD17B2 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- HTR4 | c.483G>A p.W161* | Nonsense Mutation (SNP) | VAF 43/159 reads (27%) | called by muse, mutect2, varscan2
- HYDIN | c.7294C>T p.L2432F | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF10 | c.3076T>C p.Y1026H | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL31 | c.345A>G p.I115M | Missense Mutation (SNP) | VAF 84/276 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- ILDR1 | c.961G>A p.G321S (on ENST00000344209 / NM_001199799.2; = p.G277S on NM_175924.4) | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ILDR2 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- IMPG1 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- INPPL1 | c.3323C>T p.T1108I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- IRS1 | c.2284C>T p.L762F | Missense Mutation (SNP) | VAF 174/581 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ITGB6 | c.2182T>G p.C728G | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITIH6 | c.869T>A p.V290E | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- JAKMIP2 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 72/257 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KATNB1 | c.1653G>A p.W551* | Nonsense Mutation (SNP) | VAF 58/187 reads (31%) | called by muse, mutect2, varscan2
- KCTD16 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KIDINS220 | c.2645C>T p.S882L | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- LINGO2 | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- LRP2 | c.12846C>G p.D4282E | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- LRRC39 | c.180T>G p.D60E | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- MAGEE2 | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAML3 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 100/226 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.191); called by muse, mutect2
- MAP3K4 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCHF10 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 102/326 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- MED12L | c.3445G>A p.G1149S | Missense Mutation (SNP) | VAF 111/413 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- MED23 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MEIS2 | c.643C>T p.P215S (on ENST00000561208 / NM_170675.5; = p.P202S on NM_002399.3) | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MEP1B | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMP1 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- MON2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- MS4A12 | c.276G>A p.G92= | Splice Region (SNP) | VAF 25/96 reads (26%) | called by muse, mutect2, varscan2
- MTMR8 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC12 | c.9770C>T p.S3257L (on ENST00000379442; = p.S3114L on NM_001164462.1) | Missense Mutation (SNP) | VAF 224/4024 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- MUC16 | c.19891G>A p.D6631N | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- MUC22 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 109/575 reads (19%) | SIFT tolerated (0.6); called by muse, mutect2, varscan2
- MXRA5 | c.3779C>T p.S1260F | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MYCBP2 | c.8648C>T p.P2883L (on ENST00000357337; = p.P2921L on NM_015057.5) | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MYH1 | c.2435+1G>A p.X812_splice | Splice Site (SNP) | VAF 50/163 reads (31%) | called by muse, mutect2, varscan2
- MYO3B | c.3910G>A p.E1304K | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- MYOCD | c.2186A>T p.Q729L | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MYRFL | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NAF1 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCAN | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- NEK11 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NELFE | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 67/441 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NLRP10 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- NLRP14 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP5 | c.2660C>T p.S887F | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- NOTCH1 | c.2243C>T p.T748I | Missense Mutation (SNP) | VAF 119/422 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- NOX1 | c.1083G>A p.W361* | Nonsense Mutation (SNP) | VAF 30/137 reads (22%) | called by muse, mutect2
- NRK | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NUDCD1 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUTM2B | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- OPLAH | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 144/939 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPN1MW | c.977A>G p.N326S | Missense Mutation (SNP) | VAF 67/282 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR10J1 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR11L1 | c.556dup p.Q186Pfs*84 | Frame Shift Ins (INS) | VAF 64/372 reads (17%) | called by mutect2, pindel, varscan2
- OR13G1 | c.146A>G p.N49S | Missense Mutation (SNP) | VAF 60/271 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2
- OR2T33 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, varscan2
- OR51Q1 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- OR5V1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- OR7D2 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- P2RY2 | c.1022C>A p.S341Y | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PANX2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PAPPA2 | c.5033C>T p.S1678F | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAX6 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 89/281 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA13 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 120/456 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PCDHA8 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDHB8 | c.667A>G p.R223G | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); called by muse, varscan2
- PDCD6IP | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- PDE1C | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PDGFRL | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGG | c.2072C>T p.S691F (on ENST00000453061 / NM_001127178.3; = p.S683F on NM_017733.4) | Missense Mutation (SNP) | VAF 210/497 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PLXDC1 | c.1057G>A p.G353S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- PMS2 | c.2111A>G p.D704G | Missense Mutation (SNP) | VAF 62/403 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PNPLA5 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- POP1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 77/530 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PRAM1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- PRKAA2 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKCA | c.1137T>G p.D379E | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- PRKCD | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 105/182 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PRR23B | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 119/367 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PSMB4 | c.575A>C p.Q192P | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PTGER4 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 57/255 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PTPRN2 | c.2698A>G p.T900A | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- R3HCC1 | c.1340C>T p.P447L (on ENST00000411463; = p.P407L on NM_001136108.3) | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RADX | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RALGAPA1 | c.2507C>T p.P836L | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RASSF10 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 95/322 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP6 | c.5045T>C p.V1682A | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM20 | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RBM47 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 110/257 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- RBMXL2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RGL3 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- RHBG | c.1330A>G p.K444E | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIPK4 | c.1142C>T p.S381F (on ENST00000352483; = p.S333F on NM_020639.3) | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RNF170 | c.344G>T p.W115L | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- ROS1 | c.2842C>T p.P948S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RPRD2 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 47/333 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RUNX3 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 95/258 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SALL3 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- SCAPER | c.1264C>T p.L422F | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCGN | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- SCN10A | c.4562G>A p.G1521D | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- SEMG2 | c.1511G>A p.G504D | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SHC3 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- SHISAL2B | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- SIM1 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 43/178 reads (24%) | called by muse, mutect2, varscan2
- SIRPB2 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SKOR2 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 179/682 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SLC12A4 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC25A48 | c.371T>A p.V124E | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SLC29A4 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC35F3 | c.588G>A p.W196* (on ENST00000366617 / NM_001300845.1; = p.W265* on NM_173508.4) | Nonsense Mutation (SNP) | VAF 39/130 reads (30%) | called by muse, mutect2, varscan2
- SLC4A10 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLIT2 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMNDC1 | c.120+2T>C p.X40_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- SP4 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 204/332 reads (61%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SPAST | c.1336C>T p.L446F | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATC1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- SPIN4 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- SPRY3 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 162/545 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- STK26 | c.933G>A p.S311= | Splice Region (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- SUSD2 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYTL4 | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TAFA5 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TAS2R41 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 107/620 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- TBX15 | c.1106C>T p.S369F (on ENST00000369429 / NM_001330677.2; = p.S263F on NM_152380.3) | Missense Mutation (SNP) | VAF 131/420 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TDRD15 | c.3428G>A p.G1143E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TENM1 | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 62/209 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- TENT4B | c.1756C>T p.P586S (on ENST00000561678 / NM_001365323.2; = p.P571S on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TEX52 | c.113G>A p.W38* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2
- THOC2 | c.3035C>T p.S1012F | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- THOP1 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- TLR8 | c.988G>A p.G330R (on ENST00000218032 / NM_138636.5; = p.G348R on NM_016610.4) | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TMC3 | c.2984C>T p.S995L | Missense Mutation (SNP) | VAF 81/283 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- TRPC6 | c.40T>G p.S14A | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); called by mutect2, varscan2
- TRPM7 | c.686T>G p.L229W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); called by muse, varscan2
- TTN | c.13705G>A p.D4569N (on ENST00000591111; = p.D3642N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/119 reads (22%) | PolyPhen benign (0.189); called by muse, mutect2, varscan2
- TTN | c.11234T>C p.V3745A (on ENST00000591111; = p.V3699A on NM_003319.4) | Missense Mutation (SNP) | VAF 57/203 reads (28%) | called by muse, mutect2, varscan2
- TUBB | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 54/327 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- UBR5 | c.5441C>T p.P1814L | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- UGT2B4 | c.250A>C p.T84P | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- USH2A | c.10666G>A p.G3556R | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- USP24 | c.4987C>T p.H1663Y | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- VCP | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 161/507 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- VPS35 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- WIZ | c.4451C>T p.A1484V (on ENST00000673675 / NM_001371589.1; = p.A389V on NM_021241.3) | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- XRN2 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZAN | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 147/250 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZBTB18 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDBF2 | c.2888C>T p.P963L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZIM3 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 95/325 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZKSCAN8 | c.1733T>A p.V578D | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); called by muse, varscan2
- ZNF142 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 101/318 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- ZNF235 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF280C | c.2033G>A p.G678E | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF507 | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF606 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- ZNF729 | c.1962dup p.P655Tfs*5 | Frame Shift Ins (INS) | VAF 34/219 reads (16%) | called by pindel, varscan2
- ZNF735 | c.1121T>A p.I374N | Missense Mutation (SNP) | VAF 132/263 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ABCC2 | c.1836G>A p.R612= | Silent (SNP) | VAF 101/316 reads (32%) | called by muse, mutect2, varscan2
- ABCC3 | c.3072C>T p.F1024= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as rs1417320907; called by muse, mutect2, varscan2
- ABHD13 | c.342C>T p.S114= | Silent (SNP) | VAF 46/80 reads (58%) | catalogued as COSV101024037; called by muse, mutect2, varscan2
- ABHD4 | c.450C>T p.F150= | Silent (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- ACD | c.153C>T p.L51= | Silent (SNP) | VAF 92/350 reads (26%) | catalogued as rs1207134820, COSV54665585, COSV54667112, COSV54669526; called by muse, mutect2, varscan2
- ADAM28 | c.246C>T p.G82= | Silent (SNP) | VAF 23/116 reads (20%) | called by muse, mutect2, varscan2
- ADAM29 | c.1947C>T p.D649= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as rs751802258; called by muse, mutect2, varscan2
- ADAMTS16 | c.573C>T p.L191= | Silent (SNP) | VAF 67/240 reads (28%) | catalogued as rs373309305; called by muse, mutect2, varscan2
- AGXT2 | c.930G>A p.V310= | Silent (SNP) | VAF 100/404 reads (25%) | catalogued as rs751247124, COSV99183716; called by muse, mutect2, varscan2
- AKNA | c.1359C>T p.L453= | Silent (SNP) | VAF 103/384 reads (27%) | catalogued as rs140544301; called by muse, mutect2, varscan2
- ANK2 | c.3219C>T p.F1073= | Silent (SNP) | VAF 167/400 reads (42%) | catalogued as COSV52185380; called by muse, mutect2, varscan2
- ANK2 | c.4158C>T p.F1386= | Silent (SNP) | VAF 62/178 reads (35%) | catalogued as rs567608851, COSV52149537, COSV52173810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO4 | c.1845C>T p.L615= (on ENST00000392977 / NM_001286615.2; = p.L580= on NM_178826.4) | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as rs572173243, COSV54587903; called by muse, mutect2, varscan2
- ARFGEF3 | c.417G>T p.A139= | Silent (SNP) | VAF 47/139 reads (34%) | called by muse, mutect2, varscan2
- ARID5B | c.1440C>T p.S480= | Silent (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- ASTN2 | c.3114G>A p.G1038= (on ENST00000313400 / NM_001365069.1; = p.G987= on NM_014010.5) | Silent (SNP) | VAF 78/290 reads (27%) | catalogued as rs781758780; called by muse, mutect2, varscan2
- ATAD5 | c.3870T>G p.A1290= | Silent (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- ATG2A | c.3033C>T p.F1011= | Silent (SNP) | VAF 92/288 reads (32%) | catalogued as rs376523340; called by muse, mutect2, varscan2
- ATP2B3 | c.1257C>T p.I419= | Silent (SNP) | VAF 59/255 reads (23%) | called by muse, mutect2, varscan2
- ATRNL1 | c.1317T>C p.G439= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2
- BDKRB1 | c.162G>A p.G54= | Silent (SNP) | VAF 78/285 reads (27%) | catalogued as rs1477568129, COSV53707233; called by muse, mutect2, varscan2
- BMP5 | c.147G>A p.R49= | Silent (SNP) | VAF 69/316 reads (22%) | called by muse, mutect2, varscan2
- BTBD16 | c.334C>T p.L112= | Silent (SNP) | VAF 34/156 reads (22%) | catalogued as rs745344769, COSV53263218; called by muse, mutect2, varscan2
- C10orf71 | c.3262C>T p.L1088= | Silent (SNP) | VAF 74/252 reads (29%) | called by muse, mutect2, varscan2
- C11orf80 | c.771C>T p.F257= | Silent (SNP) | VAF 39/145 reads (27%) | catalogued as rs758026448; called by muse, mutect2, varscan2
- C16orf82 | c.19C>T p.L7= | Silent (SNP) | VAF 99/333 reads (30%) | catalogued as rs1052967387; called by muse, mutect2, varscan2
- CACNA1C | c.5514C>T p.P1838= | Silent (SNP) | VAF 72/205 reads (35%) | called by muse, mutect2, varscan2
- CACNA1S | c.4530C>T p.I1510= | Silent (SNP) | VAF 124/365 reads (34%) | called by muse, mutect2, varscan2
- CAND2 | c.1263C>T p.T421= (on ENST00000456430 / NM_001162499.2; = p.T328= on NM_012298.3) | Silent (SNP) | VAF 70/158 reads (44%) | called by muse, mutect2, varscan2
- CCDC158 | c.2457G>A p.Q819= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as rs755792610; called by muse, mutect2, varscan2
- CCDC170 | c.768G>A p.L256= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- CCDC9 | c.63C>T p.I21= | Silent (SNP) | VAF 74/309 reads (24%) | catalogued as rs779356635, COSV55721125; called by muse, mutect2, varscan2
- CCDC93 | c.1464C>T p.V488= | Silent (SNP) | VAF 35/146 reads (24%) | called by muse, mutect2, varscan2
- CCT8L2 | c.777C>T p.A259= | Silent (SNP) | VAF 100/319 reads (31%) | catalogued as COSV63462654; called by muse, mutect2, varscan2
- CD109 | c.4125A>G p.Q1375= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- CD163 | c.1656C>T p.S552= | Silent (SNP) | VAF 37/144 reads (26%) | called by muse, mutect2, varscan2
- CD320 | c.126C>T p.T42= | Silent (SNP) | VAF 77/266 reads (29%) | catalogued as rs551205813; called by muse, mutect2, varscan2
- CDH16 | c.2055C>T p.I685= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs766156376, COSV55334532; called by muse, mutect2, varscan2
- CDH6 | c.1797C>T p.S599= | Silent (SNP) | VAF 86/276 reads (31%) | called by muse, mutect2, varscan2
- CEP135 | c.606T>C p.A202= | Silent (SNP) | VAF 39/138 reads (28%) | called by muse, mutect2, varscan2
- CFAP251 | c.3168T>C p.G1056= | Silent (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- CFAP47 | c.783C>T p.F261= | Silent (SNP) | VAF 45/178 reads (25%) | catalogued as COSV52893072; called by muse, mutect2, varscan2
- CFAP47 | c.1614G>A p.S538= | Silent (SNP) | VAF 67/170 reads (39%) | catalogued as COSV52888570; called by muse, mutect2, varscan2
- COG6 | c.663G>A p.T221= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as rs746682554, COSV62998089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL11A1 | c.1119G>A p.L373= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as rs1434720892; called by muse, mutect2, varscan2
- CRY2 | c.1227C>T p.F409= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as COSV69889089; called by muse, mutect2, varscan2
- CYP2A7 | c.504C>T p.I168= | Silent (SNP) | VAF 48/134 reads (36%) | catalogued as rs775078619; called by muse, mutect2, varscan2
- CYP2C19 | c.1275C>T p.F425= | Silent (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- CYP2C9 | c.504C>T p.F168= | Silent (SNP) | VAF 63/206 reads (31%) | called by muse, mutect2, varscan2
- DDR1 | c.1185C>T p.F395= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs1346154689, COSV61321131; called by muse, mutect2, varscan2
- DECR2 | c.621C>T p.A207= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs1454418233; called by muse, mutect2, varscan2
- DGKI | c.783G>A p.G261= | Silent (SNP) | VAF 38/207 reads (18%) | catalogued as rs777363541, COSV99936812; called by muse, mutect2, varscan2
- DNAH10 | c.7449G>A p.R2483= (on ENST00000409039; = p.R2422= on NM_207437.3) | Silent (SNP) | VAF 45/125 reads (36%) | called by muse, mutect2, varscan2
- DNAH5 | c.10737A>G p.Q3579= | Silent (SNP) | VAF 30/144 reads (21%) | called by muse, mutect2, varscan2
- DNAH5 | c.8364C>T p.F2788= | Silent (SNP) | VAF 63/197 reads (32%) | catalogued as COSV54241051; called by muse, mutect2, varscan2
- DNAH5 | c.5994G>A p.G1998= | Silent (SNP) | VAF 56/204 reads (27%) | catalogued as COSV54219587; called by muse, mutect2, varscan2
- DNAH7 | c.5988G>A p.K1996= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV56776230; called by muse, mutect2, varscan2
- DNAJC16 | c.1431C>T p.I477= | Silent (SNP) | VAF 41/176 reads (23%) | called by muse, mutect2, varscan2
- DOK7 | c.414C>T p.L138= | Silent (SNP) | VAF 339/757 reads (45%) | catalogued as rs771995943, CS127113; called by muse, mutect2, varscan2
- DPP6 | c.1431C>T p.I477= (on ENST00000377770 / NM_001364500.2; = p.I415= on NM_001936.5) | Silent (SNP) | VAF 93/194 reads (48%) | called by muse, mutect2, varscan2
- DPYS | c.303C>T p.F101= | Silent (SNP) | VAF 222/602 reads (37%) | catalogued as rs141057778; called by muse, mutect2, varscan2
- DSP | c.6744G>A p.E2248= | Silent (SNP) | VAF 71/430 reads (17%) | called by muse, mutect2, varscan2
- DTHD1 | c.1548G>A p.K516= (on ENST00000456874; = p.K351= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 112/276 reads (41%) | called by muse, mutect2, varscan2
- ELANE | c.495C>T p.I165= | Silent (SNP) | VAF 147/388 reads (38%) | catalogued as rs200923638, COSV55048181; called by muse, mutect2, varscan2
- ELFN1 | c.1749C>T p.F583= | Silent (SNP) | VAF 65/339 reads (19%) | catalogued as rs1477754847; called by muse, varscan2
- ELOA3D | c.819C>T p.P273= | Silent (SNP) | VAF 126/2608 reads (5%) | called by muse, mutect2
- EMSY | c.3711C>T p.F1237= | Silent (SNP) | VAF 39/116 reads (34%) | called by muse, mutect2, varscan2
- ENAM | c.2772C>T p.S924= | Silent (SNP) | VAF 193/471 reads (41%) | catalogued as rs762153305; called by muse, mutect2, varscan2
- ENPP1 | c.174G>A p.E58= | Silent (SNP) | VAF 49/160 reads (31%) | catalogued as rs1337975655; called by muse, mutect2, varscan2
- EPHA1 | c.279C>T p.S93= | Silent (SNP) | VAF 180/882 reads (20%) | called by muse, mutect2, varscan2
- EPHA10 | c.702G>A p.V234= | Silent (SNP) | VAF 53/194 reads (27%) | catalogued as rs1302356350; called by muse, mutect2, varscan2
- EXOC1 | c.138C>T p.R46= | Silent (SNP) | VAF 40/155 reads (26%) | called by muse, mutect2, varscan2
- EYA4 | c.996C>T p.F332= (on ENST00000531901 / NM_001301013.1; = p.F326= on NM_004100.5) | Silent (SNP) | VAF 72/211 reads (34%) | catalogued as rs773095472, CM138393, COSV62049831; called by muse, mutect2, varscan2
- FAM120C | c.2019G>A p.R673= | Silent (SNP) | VAF 29/113 reads (26%) | called by muse, mutect2, varscan2
- FAM83C | c.1233G>A p.R411= | Silent (SNP) | VAF 60/195 reads (31%) | called by muse, mutect2, varscan2
- FBXL7 | c.1299C>T p.L433= | Silent (SNP) | VAF 99/344 reads (29%) | catalogued as rs1448785651; called by muse, mutect2, varscan2
- FER1L6 | c.5511C>T p.F1837= | Silent (SNP) | VAF 100/200 reads (50%) | catalogued as rs1416395020; called by muse, mutect2, varscan2
- FHIT | c.15T>C p.F5= | Silent (SNP) | VAF 44/67 reads (66%) | called by muse, mutect2, varscan2
- FILIP1 | c.3303G>A p.K1101= | Silent (SNP) | VAF 60/190 reads (32%) | called by muse, mutect2, varscan2
- FIP1L1 | c.1389A>G p.R463= | Silent (SNP) | VAF 120/491 reads (24%) | called by muse, varscan2
- FLG | c.1092C>T p.S364= | Silent (SNP) | VAF 318/786 reads (40%) | called by muse, mutect2, varscan2
- FNDC1 | c.1989C>T p.F663= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs970040364, COSV51933126, COSV51939462; called by muse, mutect2, varscan2
- FNDC3B | c.2595C>T p.S865= | Silent (SNP) | VAF 108/336 reads (32%) | catalogued as rs748036776; called by muse, mutect2, varscan2
- FOLH1 | c.2013G>A p.L671= | Silent (SNP) | VAF 13/49 reads (27%) | called by muse, varscan2
- FRMPD4 | c.255C>T p.P85= | Silent (SNP) | VAF 54/280 reads (19%) | catalogued as rs769101701; ClinVar: likely benign; called by muse, mutect2, varscan2
- GABRD | c.909G>A p.R303= | Silent (SNP) | VAF 190/667 reads (28%) | catalogued as COSV66080686; called by muse, mutect2, varscan2
- GDPD4 | c.822C>T p.F274= | Silent (SNP) | VAF 49/174 reads (28%) | catalogued as rs1172008580, COSV60023462; called by muse, mutect2, varscan2
- GIPR | c.828C>T p.I276= | Silent (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- GLI2 | c.297C>T p.S99= | Silent (SNP) | VAF 44/142 reads (31%) | called by muse, mutect2, varscan2
- GRXCR2 | c.252G>A p.R84= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as rs746102300, COSV65060724; called by muse, mutect2, varscan2
- HBG2 | c.357C>T p.F119= | Silent (SNP) | VAF 86/427 reads (20%) | catalogued as rs750889658, COSV57964338; called by muse, mutect2, varscan2
- HDAC7 | c.531C>T p.L177= (on ENST00000427332; = p.L216= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV50318474; called by muse, mutect2, varscan2
- HGD | c.1263G>A p.E421= | Silent (SNP) | VAF 79/284 reads (28%) | catalogued as COSV52197186; called by muse, mutect2, varscan2
- HID1 | c.1164C>T p.F388= | Silent (SNP) | VAF 55/138 reads (40%) | catalogued as rs1262886212, COSV59351139; called by muse, mutect2, varscan2
- HIF1A | c.1959T>C p.S653= | Silent (SNP) | VAF 80/239 reads (33%) | called by muse, mutect2, varscan2
- HMCN2 | c.4488C>T p.I1496= | Silent (SNP) | VAF 50/188 reads (27%) | called by muse, mutect2, varscan2
- HOOK2 | c.2070C>T p.F690= | Silent (SNP) | VAF 66/257 reads (26%) | catalogued as rs747678560, COSV99244744; called by muse, mutect2, varscan2
- HPS3 | c.1521C>T p.S507= | Silent (SNP) | VAF 34/168 reads (20%) | catalogued as rs1252506587; called by muse, mutect2, varscan2
- HSF1 | c.663C>T p.S221= | Silent (SNP) | VAF 96/627 reads (15%) | catalogued as rs782550406; called by muse, mutect2, varscan2
- HYDIN | c.4416G>A p.Q1472= | Silent (SNP) | VAF 19/82 reads (23%) | called by mutect2, varscan2
- IGHV3-21 | c.109C>T p.L37= | Silent (SNP) | VAF 76/424 reads (18%) | catalogued as rs782817560; called by muse, varscan2
- IGKV6D-21 | c.270C>T p.F90= | Silent (SNP) | VAF 76/244 reads (31%) | called by muse, mutect2, varscan2
- IGSF9B | c.3141C>T p.F1047= | Silent (SNP) | VAF 56/224 reads (25%) | catalogued as rs757925560, COSV58064152, COSV58067565; called by muse, mutect2, varscan2
- IL17RA | c.1332C>T p.I444= | Silent (SNP) | VAF 130/474 reads (27%) | catalogued as rs1462547837, COSV60051216; called by muse, mutect2, varscan2
- IQANK1 | c.33A>C p.A11= | Silent (SNP) | VAF 64/497 reads (13%) | called by muse, mutect2, varscan2
- ISG15 | c.87G>A p.K29= | Silent (SNP) | VAF 58/211 reads (27%) | called by muse, mutect2, varscan2
- KCNB2 | c.405C>T p.S135= | Silent (SNP) | VAF 36/283 reads (13%) | catalogued as COSV101579035; called by muse, varscan2
- KCNB2 | c.954G>A p.S318= | Silent (SNP) | VAF 29/414 reads (7%) | catalogued as rs747892646; called by muse, mutect2
- KCND2 | c.252C>T p.F84= | Silent (SNP) | VAF 435/848 reads (51%) | catalogued as rs1282232580, COSV58576379, COSV58585770; called by muse, mutect2, varscan2
- KCNH5 | c.2103C>T p.P701= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as rs112731796, COSV59770233; ClinVar: likely benign; called by muse, varscan2
- KCNH7 | c.351C>T p.N117= | Silent (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- KIF13A | c.5091C>T p.G1697= | Silent (SNP) | VAF 90/368 reads (24%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.141C>T p.I47= (on ENST00000396284; = p.I8= on NM_001080770.2) | Silent (SNP) | VAF 97/318 reads (31%) | called by muse, mutect2, varscan2
- KIR3DL1 | c.228C>T p.F76= | Silent (SNP) | VAF 81/301 reads (27%) | called by muse, mutect2, varscan2
- KLF17 | c.975C>T p.F325= | Silent (SNP) | VAF 97/273 reads (36%) | catalogued as COSV64856345; called by muse, mutect2, varscan2
- KLHDC7A | c.2259C>T p.F753= | Silent (SNP) | VAF 79/285 reads (28%) | called by muse, mutect2, varscan2
- KLHL13 | c.1617C>T p.V539= | Silent (SNP) | VAF 61/234 reads (26%) | called by muse, mutect2, varscan2
- KRT26 | c.243G>A p.G81= | Silent (SNP) | VAF 96/330 reads (29%) | called by muse, mutect2, varscan2
- L1CAM | c.3501G>A p.P1167= | Silent (SNP) | VAF 182/600 reads (30%) | catalogued as rs1557089616, COSV62826715; called by muse, mutect2, varscan2
- LHFPL1 | c.6G>A p.R2= | Silent (SNP) | VAF 69/252 reads (27%) | catalogued as COSV64332893; called by muse, mutect2, varscan2
- LHX1 | c.753C>T p.F251= | Silent (SNP) | VAF 165/518 reads (32%) | called by muse, mutect2, varscan2
- LILRB1 | c.903C>T p.F301= (on ENST00000427581; = p.F265= on NM_006669.6) | Silent (SNP) | VAF 102/389 reads (26%) | catalogued as COSV61116452, COSV61116772, COSV61122370; called by muse, mutect2, varscan2
- LILRB4 | c.1191G>A p.Q397= (on ENST00000391733 / NM_001278428.3; = p.Q396= on NM_001278426.3) | Silent (SNP) | VAF 127/475 reads (27%) | called by muse, mutect2, varscan2
- LINGO2 | c.1200C>T p.A400= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as rs1235734992; called by muse, mutect2, varscan2
- LNX1 | c.120C>T p.I40= | Silent (SNP) | VAF 77/348 reads (22%) | catalogued as rs764417661, COSV55784694; called by muse, mutect2, varscan2
- LOXHD1 | c.3987C>T p.I1329= | Silent (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- LPA | c.2859C>T p.F953= | Silent (SNP) | VAF 95/375 reads (25%) | catalogued as rs1429400091; called by muse, mutect2, varscan2
- LPIN1 | c.30C>T p.S10= | Silent (SNP) | VAF 58/268 reads (22%) | called by muse, mutect2, varscan2
- LRRC19 | c.324C>T p.S108= | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- LRRC52 | c.927C>T p.F309= | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as rs1383252850; called by muse, mutect2, varscan2
- LRRIQ4 | c.393G>A p.K131= | Silent (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- LTN1 | c.177T>C p.S59= | Silent (SNP) | VAF 36/149 reads (24%) | called by mutect2, varscan2
- MCM3AP | c.3117A>G p.S1039= | Silent (SNP) | VAF 48/158 reads (30%) | called by muse, mutect2, varscan2
- MDN1 | c.6117G>T p.L2039= | Silent (SNP) | VAF 113/316 reads (36%) | called by muse, mutect2, varscan2
- MEX3B | c.867C>T p.S289= | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as rs745615618; called by muse, mutect2, varscan2
- MGAM2 | c.3294C>T p.F1098= | Silent (SNP) | VAF 254/470 reads (54%) | called by muse, mutect2, varscan2
- MINDY4 | c.1098C>T p.D366= | Silent (SNP) | VAF 135/237 reads (57%) | called by muse, mutect2, varscan2
- MLH1 | c.813C>T p.S271= | Silent (SNP) | VAF 83/198 reads (42%) | catalogued as CD093760; called by muse, mutect2, varscan2
- MLIP | c.96G>A p.L32= | Silent (SNP) | VAF 61/390 reads (16%) | catalogued as COSV51427807; called by muse, mutect2, varscan2
- MMP9 | c.93C>T p.F31= | Silent (SNP) | VAF 125/494 reads (25%) | catalogued as rs200436945; called by muse, mutect2, varscan2
- MOSMO | c.267C>T p.S89= | Silent (SNP) | VAF 90/286 reads (31%) | called by muse, mutect2, varscan2
- MPST | c.156C>T p.R52= (on ENST00000341116 / NM_001369904.2; = p.R72= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/305 reads (27%) | called by muse, mutect2, varscan2
- MUC12 | c.5781C>T p.F1927= (on ENST00000379442; = p.F1784= on NM_001164462.1) | Silent (SNP) | VAF 182/259 reads (70%) | called by muse, mutect2, varscan2
- MUC12 | c.14280C>T p.F4760= (on ENST00000379442; = p.F4617= on NM_001164462.1) | Silent (SNP) | VAF 201/347 reads (58%) | catalogued as rs878876115; called by muse, mutect2, varscan2
- MUC16 | c.13965C>T p.F4655= | Silent (SNP) | VAF 49/151 reads (32%) | catalogued as rs1196346334, COSV67455345; called by muse, mutect2, varscan2
- MUC21 | c.6G>A p.K2= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV66220363; called by muse, mutect2, varscan2
- MUC4 | c.9189C>T p.S3063= | Silent (SNP) | VAF 136/428 reads (32%) | called by muse, varscan2
- MYH2 | c.1602C>T p.F534= | Silent (SNP) | VAF 35/177 reads (20%) | called by muse, mutect2, varscan2
- MYH4 | c.3684G>A p.L1228= | Silent (SNP) | VAF 44/134 reads (33%) | called by muse, mutect2
- MYH4 | c.714C>T p.T238= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs757676293, COSV99701280; called by muse, mutect2, varscan2
- MYO18B | c.4068C>T p.F1356= | Silent (SNP) | VAF 49/166 reads (30%) | called by muse, mutect2, varscan2
- MYO18B | c.4998G>A p.Q1666= | Silent (SNP) | VAF 59/258 reads (23%) | catalogued as rs1370909942, COSV59133795; called by muse, mutect2, varscan2
- NBEA | c.705C>T p.F235= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs767011945; called by muse, mutect2, varscan2
- NCKAP1L | c.2616G>A p.V872= | Silent (SNP) | VAF 65/210 reads (31%) | catalogued as COSV99514892; called by muse, mutect2, varscan2
- NCR3 | c.360G>A p.G120= | Silent (SNP) | VAF 50/267 reads (19%) | catalogued as rs1173897984; called by muse, mutect2, varscan2
- NLRP2 | c.1992G>A p.E664= | Silent (SNP) | VAF 68/241 reads (28%) | catalogued as COSV99672598; called by muse, mutect2, varscan2
- NPBWR1 | c.243C>T p.I81= | Silent (SNP) | VAF 202/694 reads (29%) | called by muse, mutect2, varscan2
- NRG3 | c.1845G>A p.G615= (on ENST00000404547 / NM_001370084.1; = p.G591= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 87/298 reads (29%) | catalogued as rs867852560; called by muse, mutect2, varscan2
- NTN4 | c.141C>T p.L47= | Silent (SNP) | VAF 48/238 reads (20%) | called by muse, mutect2, varscan2
- OBP2B | c.184T>C p.L62= | Silent (SNP) | VAF 63/223 reads (28%) | called by muse, mutect2, varscan2
- OR1D2 | c.276C>T p.I92= | Silent (SNP) | VAF 180/605 reads (30%) | called by muse, mutect2, varscan2
- OR1L1 | c.261C>T p.I87= (on ENST00000373686; = p.I37= on NM_001005236.3) | Silent (SNP) | VAF 47/177 reads (27%) | called by muse, mutect2, varscan2
- OR2T3 | c.537C>T p.I179= | Silent (SNP) | VAF 60/398 reads (15%) | catalogued as rs965460968, COSV62083179; called by muse, mutect2
- OR2T34 | c.537C>T p.I179= | Silent (SNP) | VAF 134/340 reads (39%) | called by muse, varscan2
- OR4N2 | c.255C>T p.F85= | Silent (SNP) | VAF 50/354 reads (14%) | catalogued as rs139052676, COSV60052198; called by muse, varscan2
- OR4N2 | c.318C>T p.F106= | Silent (SNP) | VAF 82/594 reads (14%) | called by muse, varscan2
- OR4S1 | c.891G>A p.R297= | Silent (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
- OR51V1 | c.462G>A p.R154= | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as rs867904279, COSV58314319; called by muse, mutect2, varscan2
- OR5B2 | c.777G>A p.Q259= | Silent (SNP) | VAF 76/299 reads (25%) | called by muse, mutect2, varscan2
- OR5D14 | c.471C>T p.G157= | Silent (SNP) | VAF 84/253 reads (33%) | catalogued as rs142746293; called by muse, mutect2, varscan2
- OR5D16 | c.129G>A p.G43= | Silent (SNP) | VAF 25/138 reads (18%) | called by muse, mutect2, varscan2
- OR5P3 | c.903G>A p.L301= | Silent (SNP) | VAF 71/200 reads (36%) | catalogued as rs1342345443; called by muse, mutect2, varscan2
- OR5T2 | c.750C>T p.I250= | Silent (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- OR6C75 | c.492G>A p.L164= | Silent (SNP) | VAF 99/312 reads (32%) | called by muse, varscan2
- OR8I2 | c.411C>T p.S137= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as COSV100135774, COSV100136036; called by muse, mutect2, varscan2
- P3H2 | c.435C>T p.F145= | Silent (SNP) | VAF 64/210 reads (30%) | called by muse, mutect2, varscan2
- PABPC1L2B | c.189G>A p.L63= | Silent (SNP) | VAF 74/568 reads (13%) | called by muse, mutect2
- PALLD | c.990C>T p.I330= | Silent (SNP) | VAF 35/140 reads (25%) | called by muse, mutect2, varscan2
- PASD1 | c.1956G>A p.Q652= | Silent (SNP) | VAF 58/181 reads (32%) | called by muse, mutect2, varscan2
- PCDHB15 | c.2004G>A p.Q668= | Silent (SNP) | VAF 163/599 reads (27%) | catalogued as rs781997741; called by muse, mutect2, varscan2
- PCSK5 | c.3672G>A p.R1224= | Silent (SNP) | VAF 52/148 reads (35%) | catalogued as COSV70448177; called by muse, mutect2, varscan2
- PDE1C | c.390C>T p.I130= | Silent (SNP) | VAF 157/261 reads (60%) | catalogued as rs776103841; called by muse, mutect2, varscan2
- PGLYRP4 | c.927C>T p.F309= | Silent (SNP) | VAF 63/254 reads (25%) | catalogued as COSV62834487; called by muse, mutect2, varscan2
- PHLDB2 | c.2436C>T p.S812= (on ENST00000393925 / NM_001134439.2; = p.S769= on NM_145753.2) | Silent (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2
- PIAS4 | c.81G>C p.V27= | Silent (SNP) | VAF 58/183 reads (32%) | called by muse, varscan2
- PIM2 | c.867A>T p.P289= | Silent (SNP) | VAF 53/200 reads (27%) | called by muse, mutect2, varscan2
- PKP2 | c.1404G>A p.R468= | Silent (SNP) | VAF 50/172 reads (29%) | called by muse, varscan2
- PLCG2 | c.1917C>T p.N639= | Silent (SNP) | VAF 82/315 reads (26%) | called by muse, mutect2, varscan2
- PLCH1 | c.4932G>A p.G1644= (on ENST00000340059 / NM_001130960.2; = p.G1636= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/204 reads (31%) | called by muse, mutect2, varscan2
- PLXNA2 | c.2661C>T p.F887= | Silent (SNP) | VAF 65/202 reads (32%) | called by muse, mutect2, varscan2
- POLR3A | c.579C>T p.F193= | Silent (SNP) | VAF 80/249 reads (32%) | catalogued as COSV64931061; called by muse, mutect2, varscan2
- POMK | c.804C>T p.F268= | Silent (SNP) | VAF 54/175 reads (31%) | called by muse, mutect2, varscan2
- POU5F1 | c.297A>G p.A99= | Silent (SNP) | VAF 69/417 reads (17%) | catalogued as rs141749005; called by muse, mutect2, varscan2
- PPM1J | c.1431C>T p.G477= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV53518871; called by muse, mutect2, varscan2
- PPP1R3A | c.1017G>A p.R339= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs1279895466, COSV52894341; called by muse, mutect2, varscan2
- PRAMEF10 | c.114G>A p.L38= | Silent (SNP) | VAF 33/95 reads (35%) | called by mutect2, varscan2
- PRAMEF14 | c.420G>A p.R140= | Silent (SNP) | VAF 131/467 reads (28%) | called by muse, mutect2, varscan2
- PRAMEF15 | c.528G>A p.R176= | Silent (SNP) | VAF 111/481 reads (23%) | called by muse, mutect2, varscan2
- PRKN | c.1021C>T p.L341= | Silent (SNP) | VAF 67/240 reads (28%) | called by muse, mutect2, varscan2
- PRRC2B | c.5811C>T p.P1937= | Silent (SNP) | VAF 69/204 reads (34%) | catalogued as rs1239103205; called by muse, mutect2, varscan2
- PRSS35 | c.690G>A p.G230= | Silent (SNP) | VAF 53/147 reads (36%) | called by muse, mutect2, varscan2
- PSD3 | c.580T>C p.L194= | Silent (SNP) | VAF 40/119 reads (34%) | called by muse, mutect2, varscan2
- PSG1 | c.1233C>T p.V411= | Silent (SNP) | VAF 62/222 reads (28%) | catalogued as rs528449196, COSV54945043; called by muse, mutect2, varscan2
- RBM47 | c.345C>T p.F115= | Silent (SNP) | VAF 54/317 reads (17%) | catalogued as rs757455816, COSV55938178; called by muse, mutect2, varscan2
- REXO5 | c.582G>A p.K194= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- RGPD4 | c.5097G>A p.R1699= | Silent (SNP) | VAF 106/323 reads (33%) | called by muse, mutect2, varscan2
- RPL14 | c.498C>T p.I166= | Silent (SNP) | VAF 179/309 reads (58%) | catalogued as rs753658672; called by muse, mutect2, varscan2
- RPN1 | c.1473C>T p.G491= | Silent (SNP) | VAF 131/411 reads (32%) | called by muse, mutect2, varscan2
- RPTN | c.708G>A p.Q236= | Silent (SNP) | VAF 76/264 reads (29%) | catalogued as COSV100285695, COSV60167021; called by muse, mutect2, varscan2
- RYR1 | c.5082G>A p.L1694= | Silent (SNP) | VAF 82/279 reads (29%) | called by muse, mutect2, varscan2
- SBK2 | c.633G>A p.G211= | Silent (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- SCGN | c.552C>T p.F184= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs267600904, COSV58546226; called by muse, mutect2, varscan2
- SCNN1B | c.1650C>T p.I550= | Silent (SNP) | VAF 135/458 reads (29%) | catalogued as COSV56305825; called by muse, mutect2, varscan2
177 further variants in this file (0 protein-altering or splice-affecting, 71 silent, 106 other) are not listed here.
